Somatic mutation profile of tumor specimen TCGA-P4-AAVM-01A (aliquot TCGA-P4-AAVM-01A-11D-A42J-10) from TCGA case TCGA-P4-AAVM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.2 years (25,280 days).
Specimen TCGA-P4-AAVM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 575ea650-dbb5-4bbd-9c8e-18fcfb230cb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-AAVM-11A (Solid Tissue Normal), aliquot TCGA-P4-AAVM-11A-11D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/726e7315-7379-4865-bae2-20cb77fd9d53

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 19, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99603923; called by muse, mutect2, varscan2
- ALX3 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV100873898; called by muse, mutect2, varscan2
- ANKRA2 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99707112; called by muse, mutect2, varscan2
- ANKRD34B | c.1530A>C p.Q510H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100103627; called by muse, mutect2, varscan2
- ANKS6 | c.506T>C p.F169S | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100782376; called by muse, mutect2, varscan2
- ASH1L | c.8566C>T p.Q2856* (on ENST00000368346 / NM_001366177.2; = p.Q2851* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV100853573; called by muse, mutect2, varscan2
- BRCA2 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101204596; called by muse, mutect2, varscan2
- CCDC142 | c.1429T>G p.S477A (on ENST00000393965 / NM_001365575.2; = p.S470A on NM_032779.4) | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV99282321; called by muse, mutect2, varscan2
- CCDC183 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV100566075; called by muse, mutect2, varscan2
- CTSE | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV100733719, COSV63060569; called by muse, mutect2, varscan2
- DBNL | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101289380; called by muse, mutect2, varscan2
- DENND1C | c.1436dup p.S480Lfs*56 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | catalogued as rs775749909; called by mutect2, varscan2
- FGD3 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61600934; called by muse, mutect2, varscan2
- GLG1 | c.3265C>T p.Q1089* | Nonsense Mutation (SNP) | VAF 62/102 reads (61%) | catalogued as COSV99215303; called by muse, mutect2, varscan2
- GPATCH8 | c.3382C>T p.Q1128* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100132811; called by muse, mutect2, varscan2
- HECW2 | c.1980C>A p.C660* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99645683, COSV99648530; called by muse, mutect2
- HOXC8 | c.146T>A p.F49Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV99236934; called by muse, mutect2, varscan2
- HSD17B14 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.852); catalogued as COSV99622944; called by muse, mutect2, varscan2
- KIF1B | c.4056-1G>A p.X1352_splice (on ENST00000377086 / NM_001365952.1; = p.X1306_splice on NM_015074.3) | Splice Site (SNP) | VAF 7/126 reads (6%) | catalogued as COSV55813819, COSV99824032; called by muse, mutect2
- LCN15 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100293560; called by muse, mutect2, varscan2
- METTL21C | c.520dup p.E174Gfs*15 | Frame Shift Ins (INS) | VAF 50/137 reads (36%) | catalogued as rs760847518; called by mutect2, pindel, varscan2
- MYO10 | c.1985T>C p.M662T | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946089; called by muse, mutect2, varscan2
- OLA1 | c.655T>G p.F219V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV52970677, COSV99506728; called by muse, mutect2, varscan2
- PDXDC1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV100363393; called by muse, mutect2, varscan2
- PLEKHF2 | c.748T>A p.*250Kext*32 | Nonstop Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100193602; called by muse, varscan2
- PML | c.779A>C p.Q260P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV99167813; called by muse, mutect2, varscan2
- PPIL2 | c.53A>T p.Y18F | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100622745; called by muse, mutect2, varscan2
- PRKN | c.116A>T p.D39V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100630764; called by muse, mutect2, varscan2
- PRKN | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as CX093236, COSV100630765; called by muse, mutect2, varscan2
- SEC24D | c.1450C>G p.R484G | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99756629, COSV99756660; called by muse, mutect2, varscan2
- SH2D3A | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99838176; called by muse, mutect2, varscan2
- SI | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 130/239 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs143135955; called by muse, mutect2, varscan2
- SNW1 | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.84); catalogued as COSV99473234; called by muse, mutect2, varscan2
- TGOLN2 | c.533T>A p.V178D | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV99965111; called by muse, mutect2, varscan2
- TNS3 | c.3031C>G p.L1011V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV100236224; called by muse, mutect2, varscan2
- UFSP2 | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99249292; called by muse, mutect2, varscan2
- ZNF836 | c.38T>A p.V13E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV100441177; called by muse, mutect2, varscan2
- ABCA13 | c.10236A>T p.A3412= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV101447159; called by muse, mutect2, varscan2
- ANKS6 | c.1047C>T p.H349= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs760482276, COSV100782375; called by muse, mutect2, varscan2
- ARGFX | c.6G>A p.R2= | Silent (SNP) | VAF 226/380 reads (59%) | catalogued as COSV57682428; called by muse, mutect2, varscan2
- BPTF | c.5859T>C p.V1953= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100075827; called by muse, mutect2, varscan2
- CCDC81 | c.1453A>C p.R485= (on ENST00000445632 / NM_001156474.2; = p.R395= on NM_021827.4) | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as rs1166314083, COSV99564756; called by muse, mutect2, varscan2
- GPHN | c.475C>T p.L159= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100017439; called by muse, mutect2
- LCN15 | c.456C>G p.S152= | Silent (SNP) | VAF 92/209 reads (44%) | catalogued as COSV100293559; called by muse, mutect2, varscan2
- MYL4 | c.438C>T p.S146= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100733176; called by muse, mutect2, varscan2
- MYO1B | c.675T>C p.L225= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV100269849; called by muse, mutect2, varscan2
- NDUFS8 | c.207C>A p.G69= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV99142032; called by muse, mutect2, varscan2
- PLCG2 | c.2613C>G p.S871= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100842572; called by muse, mutect2
- PLEC | c.6876G>C p.A2292= (on ENST00000322810 / NM_201380.4; = p.A2182= on NM_000445.5) | Silent (SNP) | VAF 75/171 reads (44%) | catalogued as rs376957701, COSV100518100; called by muse, mutect2, varscan2
- PPP2CB | c.624A>T p.G208= | Silent (SNP) | VAF 32/330 reads (10%) | catalogued as rs747012576, COSV99646732; called by muse, mutect2
- PRICKLE1 | c.2107C>T p.L703= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV100454178; called by muse, mutect2, varscan2
- TMEM201 | c.552C>G p.A184= | Silent (SNP) | VAF 77/228 reads (34%) | catalogued as COSV100440592, COSV61051115; called by muse, mutect2, varscan2
- TMEM39B | c.1035C>T p.D345= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100298180; called by muse, mutect2, varscan2
- UBE2O | c.87C>T p.A29= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99166257; called by muse, mutect2, varscan2
- WNT7A | c.699C>T p.N233= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs760426340, COSV53199464; called by muse, mutect2, varscan2
- ZNF195 | c.1839A>G p.K613= (on ENST00000399602 / NM_001130520.3; = p.K541= on NM_007152.5) | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99138183; called by muse, mutect2, varscan2
- MIR1915 | chr10:21496806 C>T | 5'Flank (SNP) | VAF 10/74 reads (14%) | catalogued as rs1197250955, COSV101008171; called by muse, mutect2, varscan2
